Surgical pathology report (de-identified scan), TCGA case TCGA-85-6798, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Asterand, specimen TCGA-85-6798-01A (Primary Tumor).

[page 1 of 2]
Case ID			Formatted Path Report
	-6798		LUNG TISSUE CHECKLIST Specimen type: Lobectomy Tumor site: Lung Tumor size: 4 x 3 x 3 cm Histologic type: Squamous cell carcinoma Histologic grade: Moderately differentiated Tumor extent: Not specified Other tumor nodules: Not specified Lymph nodes: 2/16 positive for metastasis (Hilar 2/16) Lymphatic invasion: Not specified Venous invasion: Not specified Margins: Not specified Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: None

[page 2 of 2]
Date of Procurement

Source: NCI Genomic Data Commons file fdb6b375-e97b-47e2-9b3c-ff7a573c75f7 (TCGA-85-6798.5AA6FF8C-DB98-4B5B-A8A6-D924730F1B77.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).